Somatic mutation profile of tumor specimen TCGA-ZF-A9RN-01A (aliquot TCGA-ZF-A9RN-01A-11D-A42E-08) from TCGA case TCGA-ZF-A9RN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.9 years (24,795 days).
Specimen TCGA-ZF-A9RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98f76b31-7007-4c08-82e0-d7991c1756c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RN-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RN-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df55d1da-fe7f-42fc-91d2-4c85593c82ae

The open-access MAF lists 215 somatic variants for this specimen: 151 protein-altering or splice-affecting, 58 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 58, Nonsense Mutation 10, Splice Site 5, RNA 4, Frame Shift Del 2, Frame Shift Ins 2, 5'Flank 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4304A>G p.D1435G | Missense Mutation (SNP) | VAF 12/17 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200207299, CM053183, COSV52138128; called by muse, mutect2, varscan2
- ABCA13 | c.4615C>A p.Q1539K | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.758); catalogued as COSV70041996; called by muse, mutect2, varscan2
- ACSBG2 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV53125405, COSV53127345; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1905G>C p.L635F | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52822980; called by muse, mutect2
- ADGRG4 | c.7481T>G p.V2494G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV54965011; called by muse, mutect2, varscan2
- ALPK2 | c.1067dup p.L356Ffs*6 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | catalogued as rs756508755; called by mutect2, varscan2
- ANKRD26 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV65777852; called by muse, mutect2, varscan2
- APOB | c.10018G>C p.D3340H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51949588; called by muse, mutect2, varscan2
- ARHGAP12 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 110/174 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV60965482; called by muse, mutect2, varscan2
- ASCL1 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99902156; called by muse, mutect2
- AXIN2 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61060360; called by muse, varscan2
- AXIN2 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61056001; called by muse, varscan2
- B3GNT2 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.414); catalogued as COSV57345630; called by muse, mutect2, varscan2
- B4GALT3 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.268); catalogued as COSV60527852; called by muse, mutect2, varscan2
- BCLAF1 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | catalogued as rs1402289491, COSV99219862; called by muse, mutect2, varscan2
- C19orf47 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV63510906; called by muse, mutect2, varscan2
- CALCRL | c.320A>C p.Q107P | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV66476953; called by muse, mutect2, varscan2
- CCDC173 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV53641938, COSV53645588; called by muse, mutect2, varscan2
- CCDC80 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV52819491; called by muse, mutect2, varscan2
- CCP110 | c.2841-1G>C p.X947_splice | Splice Site (SNP) | VAF 47/114 reads (41%) | catalogued as COSV66817972; called by muse, mutect2, varscan2
- CD274 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs148141792; called by muse, mutect2, varscan2
- CFAP91 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 69/261 reads (26%) | catalogued as rs1278415257, COSV99847511; called by muse, mutect2, varscan2
- CHI3L1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs138989209; called by muse, mutect2, varscan2
- CHRM2 | c.1299C>A p.S433R | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57782582; called by muse, mutect2, varscan2
- CIP2A | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55420973; called by muse, mutect2, varscan2
- COL12A1 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs575168916, COSV59396982; called by muse, mutect2, varscan2
- COL19A1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV59585113; called by muse, mutect2, varscan2
- COL4A3 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV59258020; called by muse, mutect2, varscan2
- COL6A3 | c.3800A>G p.D1267G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55105726; called by muse, mutect2, varscan2
- COL9A1 | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs982761741, COSV57891836; called by muse, mutect2, varscan2
- COMMD9 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV54673188; called by muse, mutect2, varscan2
- CPT1C | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV54921384, COSV54921735; called by muse, mutect2, varscan2
- CRYBG1 | c.1968G>C p.K656N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64814234; called by muse, mutect2, varscan2
- CSF2RA | c.620A>T p.D207V | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62626414; called by muse, mutect2, varscan2
- CTAGE1 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV66944529; called by muse, mutect2, varscan2
- CYTH1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV63123039; called by muse, mutect2, varscan2
- DDX23 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57285861; called by muse, mutect2, varscan2
- DOCK2 | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56983070; called by muse, mutect2, varscan2
- DPY19L4 | c.1643G>C p.R548T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as COSV68963673; called by muse, mutect2, varscan2
- DST | c.16744G>C p.D5582H (on ENST00000361203 / NM_001374722.1; = p.D3279H on NM_015548.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as COSV55035893; called by muse, mutect2, varscan2
- DZIP3 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100848087; called by muse, mutect2, varscan2
- EMSY | c.2195A>G p.D732G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV58265156; called by muse, mutect2, varscan2
- ENOX2 | c.941T>C p.M314T (on ENST00000338144 / NM_001382520.1; = p.M285T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs368744008, COSV57657151; called by muse, mutect2, varscan2
- EXOSC6 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as rs1211193657, COSV99933802; called by muse, mutect2, varscan2
- FAT1 | c.4675G>A p.A1559T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1193669577, COSV71675663; called by muse, mutect2, varscan2
- FER1L6 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766353103, COSV67550997; called by muse, mutect2, varscan2
- FLG | c.6769G>C p.E2257Q | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV64247458; called by muse, mutect2, varscan2
- FZD1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55313165; called by muse, mutect2, varscan2
- GDAP2 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1253372023, COSV65613070; called by muse, mutect2, varscan2
- GFI1B | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59746717; called by muse, mutect2, varscan2
- GKN1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV65006836; called by muse, mutect2, varscan2
- GLIPR1 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56992468; called by muse, mutect2, varscan2
- GLUD2 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60151749, COSV60152907; called by muse, mutect2, varscan2
- GPATCH8 | c.1250G>C p.S417T | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59197829; called by muse, mutect2, varscan2
- GRIP1 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54039173; called by muse, mutect2, varscan2
- HLA-E | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as rs765019464, COSV64927888; called by muse, mutect2, varscan2
- HMCN1 | c.556T>A p.Y186N | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54934475; called by muse, mutect2, varscan2
- HMGN4 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV66433304; called by muse, mutect2, varscan2
- HPD | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs758064577, COSV56643437; called by muse, mutect2, varscan2
- HROB | c.1309-1G>A p.X437_splice | Splice Site (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55369910, COSV55370780; called by muse, varscan2
- HSPG2 | c.10487C>A p.S3496Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV65933948, COSV65933987; called by muse, mutect2, varscan2
- HTT | c.9046G>A p.V3016M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377159286; called by muse, mutect2, varscan2
- IBTK | c.3731C>G p.S1244C | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV60392232; called by muse, mutect2
- INTS8 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV58252948; called by muse, mutect2, varscan2
- IRGC | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775131068, COSV54985962; called by muse, mutect2, varscan2
- IRS4 | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV64535636; called by muse, mutect2, varscan2
- ISL1 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV57935430; called by muse, mutect2, varscan2
- KIAA1109 | c.7042G>T p.V2348L | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV52689385; called by muse, mutect2, varscan2
- KIF17 | c.3050G>C p.R1017P | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs377443985, COSV56121803; called by muse, mutect2, varscan2
- LCORL | c.722T>G p.I241R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.043); catalogued as rs779462912, COSV58839643; called by muse, mutect2, varscan2
- LPIN2 | c.1588A>T p.S530C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.21); catalogued as COSV55243480; called by muse, mutect2, varscan2
- LRFN2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs1387751774, COSV57833497; called by muse, mutect2
- LRGUK | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.505); catalogued as COSV53637053, COSV53642813, COSV53644111; called by muse, mutect2, varscan2
- LRP1B | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67265923; called by muse, mutect2, varscan2
- MAEL | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as rs199904572, COSV63303863; called by muse, mutect2, varscan2
- MAP3K6 | c.2584-1G>C p.X862_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV58874103; called by muse, mutect2, varscan2
- MARVELD2 | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as COSV57782095; called by muse, mutect2, varscan2
- MEGF10 | c.2877T>G p.F959L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV57255408; called by muse, mutect2, varscan2
- MGME1 | c.756G>C p.W252C | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66624682; called by muse, mutect2, varscan2
- MICALL2 | c.1448G>C p.S483T | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1033672407, COSV52518421; called by muse, mutect2, varscan2
- MTM1 | c.447A>G p.P149= | Splice Region (SNP) | VAF 32/66 reads (48%) | catalogued as rs782149231, COSV60337253; ClinVar: likely benign; called by muse, varscan2
- MYH1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV56845558, COSV56849108; called by muse, mutect2, varscan2
- MYH13 | c.5322G>C p.K1774N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52840477; called by muse, mutect2, varscan2
- NEIL3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52813142; called by muse, mutect2, varscan2
- NRP2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV55934601; called by muse, mutect2, varscan2
- NUP93 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV57433513; called by muse, mutect2, varscan2
- OBSCN | c.5635G>A p.V1879M | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs769115612, COSV52819745; called by muse, mutect2, varscan2
- OR4K17 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59648984; called by muse, mutect2, varscan2
- OR6C3 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV101110392; called by muse, mutect2, varscan2
- PCDH15 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV57310158, COSV57380217; called by muse, mutect2, varscan2
- PEG3 | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99690396; called by muse, mutect2, varscan2
- PGK1 | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV64832636; called by muse, mutect2, varscan2
- PHF2 | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769947880, COSV63683526; called by muse, mutect2, varscan2
- PLEKHH2 | c.2875G>C p.G959R | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56752367, COSV56760002; called by muse, mutect2, varscan2
- PPFIA4 | c.1940C>G p.S647C (on ENST00000447715; = p.S648C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55320520; called by muse, mutect2, varscan2
- PRKAA2 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV64806158; called by muse, mutect2, varscan2
- PRUNE2 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs1271632976, COSV65046676; called by muse, mutect2, varscan2
- PSG5 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61655184; called by muse, mutect2, varscan2
- PSG6 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.764); catalogued as COSV51836796; called by muse, mutect2
- RDH12 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV50822833; called by muse, mutect2, varscan2
- RP1 | c.4169A>T p.H1390L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55124948; called by muse, mutect2, varscan2
- RTCB | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.612); catalogued as COSV53277667; called by muse, mutect2
- RUBCN | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV56369091, COSV56373141; called by muse, mutect2, varscan2
- RXFP1 | c.2169G>T p.W723C | Missense Mutation (SNP) | VAF 82/96 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57055348; called by muse, mutect2, varscan2
- RYR3 | c.6871C>G p.L2291V (on ENST00000389232; = p.L2292V on NM_001036.6) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63109792; called by muse, varscan2
- SEMA3D | c.1907A>G p.E636G | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52402517; called by muse, mutect2, varscan2
- SEPSECS | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100259026; called by muse, mutect2, varscan2
- SGPP2 | c.375G>T p.W125C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58328410; called by muse, mutect2, varscan2
- SGSM2 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99280568; called by muse, mutect2, varscan2
- SHKBP1 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52538782, COSV52543128; called by muse, mutect2, varscan2
- SI | c.1656G>T p.W552C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52278400, COSV52295798; called by muse, mutect2, varscan2
- SIL1 | c.645+1G>C p.X215_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as CS054925, COSV54536571; called by muse, mutect2, varscan2
- SLC12A7 | c.2988_2989insT p.S997* | Frame Shift Ins (INS) | VAF 31/129 reads (24%) | catalogued as COSV53761686; called by mutect2, pindel, varscan2
- SLC22A10 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs746710712, COSV60419877; called by muse, mutect2, varscan2
- SLC24A2 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53873864; called by muse, mutect2, varscan2
- SLC5A5 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55835177; called by muse, mutect2, varscan2
- SMCHD1 | c.3725C>G p.S1242C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV55266520; called by muse, mutect2, varscan2
- SNW1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs759186141, COSV55054626; called by muse, mutect2, varscan2
- SNX14 | c.2142G>C p.M714I (on ENST00000314673 / NM_001350535.1; = p.M661I on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV59015575; called by muse, mutect2, varscan2
- SUPT6H | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV58930930; called by muse, mutect2, varscan2
- TAMALIN | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53336362, COSV53337439; called by muse, mutect2
- TEX2 | c.2553G>A p.M851I (on ENST00000583097 / NM_001288733.2; = p.M858I on NM_018469.5) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV51984983; called by muse, mutect2, varscan2
- TFG | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53750268; called by muse, mutect2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 19/24 reads (79%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TPP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV54999608; called by muse, mutect2, varscan2
- TRAM1L1 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60293084; called by muse, mutect2, varscan2
- TRAPPC10 | c.1665G>C p.E555D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV99379175; called by muse, mutect2
- TRAPPC12 | c.1939T>G p.L647V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV60851129; called by muse, mutect2, varscan2
- TRIP13 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751170326, COSV51321647; called by muse, mutect2, varscan2
- TRPV5 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs140202697; called by muse, mutect2, varscan2
- TTC14 | c.366T>A p.D122E | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56013928; called by muse, mutect2, varscan2
- TTN | c.56629G>C p.V18877L (on ENST00000591111; = p.V11453L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | PolyPhen benign (0.022); catalogued as rs1223901169, COSV60294816; called by muse, mutect2, varscan2
- UBA3 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as rs147779512; called by muse, mutect2, varscan2
- UGGT2 | c.4009-1G>C p.X1337_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100948954; called by muse, mutect2, varscan2
- UGT3A2 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56928463; called by muse, mutect2, varscan2
- UNC5D | c.2056T>A p.C686S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV54829147; called by muse, mutect2, varscan2
- VPS13A | c.5128G>C p.A1710P | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.332); catalogued as rs1325071063, COSV62437412; called by muse, mutect2, varscan2
- VPS9D1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs771610159, COSV66995190; called by muse, mutect2, varscan2
- YARS2 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV61402260, COSV61402487; called by muse, varscan2
- YARS2 | c.62C>G p.S21* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100256547; called by muse, varscan2
- ZFP42 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV58819020, COSV58819428; called by muse, mutect2, varscan2
- ZNF154 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV70745390; called by muse, mutect2
- ZNF324 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs775115485, COSV52182284; called by muse, mutect2, varscan2
- ZNF34 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV58641031; called by muse, mutect2, varscan2
- ZNF397 | c.480A>T p.Q160H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54352476, COSV54353409; called by muse, mutect2, varscan2
- ZNF518A | c.1659G>T p.L553F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs1554884066, COSV100283741; called by muse, mutect2, varscan2
- ZNF653 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV53404549; called by muse, mutect2, varscan2
- ZNF692 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60660083; called by muse, mutect2, varscan2
- ADCY4 | c.1929del p.K644Rfs*19 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- KLHL17 | c.683_693del p.E228Afs*13 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- S1PR5 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2
- AARS1 | c.1170T>C p.R390= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV55749248; called by muse, mutect2, varscan2
- ABCA12 | c.7272G>A p.S2424= (on ENST00000272895 / NM_173076.3; = p.S2106= on NM_015657.3) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs150309991; called by muse, mutect2, varscan2
- ABHD6 | c.753C>G p.V251= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV55910109; called by muse, mutect2, varscan2
- ACP2 | c.594G>A p.L198= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV57043795; called by muse, mutect2, varscan2
- ADAD1 | c.1554T>C p.F518= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV56646850; called by muse, mutect2, varscan2
- AKT1 | c.897G>C p.G299= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV62575669; called by muse, mutect2, varscan2
- CAPN5 | c.1365G>T p.R455= (on ENST00000456580; = p.R415= on NM_004055.5) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV53690748; called by muse, mutect2, varscan2
- CCDC81 | c.861G>A p.G287= (on ENST00000445632 / NM_001156474.2; = p.G197= on NM_021827.4) | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV53581143; called by muse, mutect2, varscan2
- CHST4 | c.759G>A p.Q253= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV58298226; called by muse, mutect2, varscan2
- CYP2D6 | c.654C>A p.G218= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs1450378700, CD1413525, COSV62245413; called by muse, mutect2
- DEFB110 | c.91T>C p.L31= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV64484853; called by muse, mutect2, varscan2
- DOCK11 | c.3516A>G p.G1172= | Silent (SNP) | VAF 70/233 reads (30%) | catalogued as COSV52246571; called by muse, mutect2, varscan2
- DOCK4 | c.4203G>T p.P1401= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV70239643, COSV70242347, COSV70244808; called by muse, mutect2, varscan2
- FAM155A | c.1071C>A p.S357= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV65583625; called by muse, mutect2, varscan2
- FREM1 | c.3591C>T p.I1197= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs201200414, COSV66528872; called by muse, mutect2, varscan2
- GPAM | c.1830C>A p.I610= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- GUCY1A1 | c.1138T>C p.L380= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV56655671, COSV99637581; called by muse, mutect2, varscan2
- H2BC4 | c.87G>A p.K29= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs1345869566, COSV58417455; called by muse, mutect2, varscan2
- HCFC1 | c.1317G>T p.P439= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs781810369, COSV60076799; called by muse, mutect2, varscan2
- HERC2 | c.381C>T p.A127= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs757177576, COSV55345987; called by muse, mutect2, varscan2
- HROB | c.1395G>A p.E465= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV55370797; called by muse, varscan2
- IGKV1-6 | c.180G>A p.Q60= | Silent (SNP) | VAF 66/222 reads (30%) | catalogued as rs547789263; called by muse, mutect2, varscan2
- IRAG2 | c.3123T>C p.A1041= (on ENST00000636465; = p.A86= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV63140464; called by muse, mutect2
- IRS4 | c.756C>G p.G252= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV64535639; called by muse, mutect2, varscan2
- KMT2B | c.5130C>T p.F1710= | Silent (SNP) | VAF 22/344 reads (6%) | catalogued as rs372951507; ClinVar: likely benign; called by muse, mutect2
- KMT2C | c.10443G>A p.Q3481= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV51492702; called by muse, mutect2, varscan2
- LGSN | c.906C>T p.F302= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV65728361; called by muse, mutect2, varscan2
- LOXL2 | c.2154C>T p.F718= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV56120439; called by muse, mutect2, varscan2
- MPP3 | c.402G>C p.S134= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV68199085; called by muse, mutect2, varscan2
- MYO18A | c.4620C>A p.V1540= | Silent (SNP) | VAF 74/126 reads (59%) | catalogued as COSV62871653, COSV62872412; called by muse, mutect2, varscan2
- ONECUT2 | c.1332C>T p.I444= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV101525699, COSV72153286; called by muse, mutect2
- OR2A2 | c.129C>A p.V43= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as COSV68872431; called by muse, mutect2, varscan2
- PCDHB11 | c.1377C>T p.F459= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as COSV61311456; called by muse, mutect2, varscan2
- PGK1 | c.531A>G p.V177= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs1557247637, COSV64832640; called by muse, mutect2, varscan2
- PKD1L1 | c.5028A>G p.L1676= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs556378378, COSV56975961; called by muse, mutect2, varscan2
- PPP1R16A | c.897G>A p.E299= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52954606; called by muse, mutect2, varscan2
- PTPN14 | c.2937C>T p.Y979= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV65287648; called by muse, mutect2, varscan2
- RBM10 | c.292C>A p.R98= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV61307911, COSV61308269, COSV61311988; called by muse, mutect2, varscan2
- RPL13 | c.573C>G p.L191= | Silent (SNP) | VAF 68/78 reads (87%) | catalogued as rs16966725, COSV61058197; called by muse, mutect2, varscan2
- SLC12A4 | c.258C>G p.L86= | Silent (SNP) | VAF 41/45 reads (91%) | catalogued as COSV100311427, COSV57926990, COSV57934530; called by muse, mutect2, varscan2
- SLC22A14 | c.867C>T p.I289= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs769090429, COSV56196111; called by muse, mutect2, varscan2
- SNX16 | c.324T>C p.S108= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV62036539; called by muse, mutect2, varscan2
- SPATA20 | c.885G>A p.Q295= (on ENST00000356488 / NM_001258372.1; = p.Q311= on NM_022827.4) | Silent (SNP) | VAF 111/185 reads (60%) | catalogued as COSV50065924, COSV50069536; called by muse, mutect2, varscan2
- SQSTM1 | c.1068A>G p.L356= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV52975058; called by muse, mutect2, varscan2
- STX4 | c.145C>A p.R49= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV100572990, COSV58269215; called by muse, mutect2, varscan2
- SYK | c.549G>C p.L183= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV65325877, COSV65329876; called by muse, mutect2, varscan2
- TAF4 | c.1869C>T p.L623= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1362181506, COSV53334996; called by muse, mutect2, varscan2
- THAP12 | c.378A>G p.E126= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV52612756; called by muse, mutect2, varscan2
- TIMP1 | c.51G>C p.L17= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV54483853, COSV99512253; called by muse, mutect2, varscan2
- TLR7 | c.858T>C p.F286= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV66125357; called by muse, mutect2, varscan2
- TMEM104 | c.645C>T p.F215= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs761311760, COSV59111852; called by muse, mutect2, varscan2
- TMEM120A | c.948C>G p.L316= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100115747; called by muse, mutect2, varscan2
- TMEM59L | c.628C>A p.R210= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs749681247, COSV53242355, COSV53243373; called by muse, mutect2, varscan2
- TRHDE | c.648C>G p.V216= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53862490; called by muse, mutect2, varscan2
- TUBGCP5 | c.399A>G p.K133= | Silent (SNP) | VAF 163/297 reads (55%) | called by muse, mutect2, varscan2
- ZNF341 | c.978C>T p.Y326= (on ENST00000375200 / NM_001282935.1; = p.Y319= on NM_032819.4) | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as rs1393284646, COSV61010941; called by muse, mutect2, varscan2
- ZNF551 | c.1722C>G p.L574= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV56594728; called by muse, mutect2, varscan2
- ZPBP | c.309T>C p.Y103= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV50432087; called by muse, mutect2, varscan2
- AC073310.1 | n.296G>T | RNA (SNP) | VAF 40/191 reads (21%) | catalogued as rs1262197769; called by muse, mutect2, varscan2
- HERC2P3 | n.382C>T | RNA (SNP) | VAF 28/50 reads (56%) | catalogued as rs767581582; called by muse, mutect2, varscan2
- SNORA26 | n.17G>C | RNA (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532483 T>G | 5'Flank (SNP) | VAF 17/32 reads (53%) | catalogued as COSV55270322, COSV99742904, COSV99744253; called by muse, mutect2, varscan2
- TCP10L3 | n.267G>A | RNA (SNP) | VAF 7/23 reads (30%) | catalogued as COSV64752432; called by muse, mutect2, varscan2
- UVSSA | c.*9328G>A | 3'UTR (SNP) | VAF 102/165 reads (62%) | catalogued as rs143725913; called by muse, varscan2
